Somatic mutation profile of tumor specimen TCGA-DD-A1ED-01A (aliquot TCGA-DD-A1ED-01A-11D-A152-10) from TCGA case TCGA-DD-A1ED, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G1; Age at diagnosis: 68.6 years (25,039 days).
Specimen TCGA-DD-A1ED-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dcac7a28-f8a9-4e9b-8d1d-ca656fc3ceda.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-A1ED-10A (Blood Derived Normal), aliquot TCGA-DD-A1ED-10A-01D-A152-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fd6eb9b7-caef-49b9-a15a-982e4645b7e1

The open-access MAF lists 25 somatic variants for this specimen: 18 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 4, Frame Shift Del 2, Splice Site 2, Nonsense Mutation 1, In Frame Del 1, RNA 1, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABHD1 | c.286C>A p.Q96K | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.96); PolyPhen benign (0.007); catalogued as COSV53208370; called by mutect2, varscan2
- CUBN | c.918C>G p.I306M | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.469); catalogued as COSV64725609, COSV64727937; called by muse, mutect2, varscan2
- DHDH | c.598G>T p.V200L | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs35453148, COSV55483487; called by muse, mutect2
- LAMA1 | c.2966C>A p.A989D | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.185); catalogued as COSV67544819; called by muse, mutect2, varscan2
- MAP2 | c.3476C>G p.S1159C | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.911); catalogued as COSV52309109; called by muse, mutect2, varscan2
- MOCS2 | c.88G>T p.E30* | Nonsense Mutation (SNP) | VAF 10/50 reads (20%) | catalogued as COSV63741497; called by muse, mutect2, varscan2
- PIWIL3 | c.266C>T p.P89L | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1465462094, COSV59998382; called by muse, mutect2, varscan2
- SUGT1 | c.479-1G>C p.X160_splice (on ENST00000343788 / NM_001130912.3; = p.X128_splice on NM_006704.5 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 14/177 reads (8%) | catalogued as COSV59424088; called by muse, mutect2
- TCAP | c.253T>C p.Y85H | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.977); catalogued as COSV54094280; called by muse, mutect2, varscan2
- TEX101 | c.256G>A p.E86K (on ENST00000598265 / NM_001130011.3; = p.E104K on NM_031451.4) | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (0.85); PolyPhen benign (0.01); catalogued as COSV53663290; called by muse, mutect2, varscan2
- TPX2 | c.755G>T p.S252I | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV55923070; called by muse, mutect2
- ULK2 | c.1441+1G>T p.X481_splice | Splice Site (SNP) | VAF 7/63 reads (11%) | catalogued as COSV64448737; called by muse, mutect2, varscan2
- ZNF471 | c.112T>G p.L38V | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV57293772; called by muse, mutect2
- ZSWIM2 | c.1507G>T p.V503L | Missense Mutation (SNP) | VAF 23/168 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs766394609, COSV54579996; called by muse, mutect2, varscan2
- DENND5B | c.1530del p.F510Lfs*23 | Frame Shift Del (DEL) | VAF 13/112 reads (12%) | called by mutect2, pindel, varscan2
- GRM2 | c.1866_1875del p.F623Sfs*92 | Frame Shift Del (DEL) | VAF 11/91 reads (12%) | called by mutect2, pindel, varscan2
- IL6ST | c.557_571del p.Y186_Y190del | In Frame Del (DEL) | VAF 15/170 reads (9%) | called by mutect2, pindel
- TANK | c.243C>A p.D81E | Missense Mutation (SNP) | VAF 82/466 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, varscan2
- CHAMP1 | c.327T>C p.P109= | Silent (SNP) | VAF 20/138 reads (14%) | catalogued as COSV63523311; called by muse, mutect2, varscan2
- LRRCC1 | c.331C>T p.L111= | Silent (SNP) | VAF 18/90 reads (20%) | catalogued as COSV64483274, COSV64486012; called by muse, mutect2, varscan2
- SLC10A2 | c.924T>C p.Y308= | Silent (SNP) | VAF 28/185 reads (15%) | catalogued as COSV55361904; called by muse, varscan2
- TUBA1B | c.1020C>T p.S340= | Silent (SNP) | VAF 26/156 reads (17%) | catalogued as rs763375689, COSV60138535; called by muse, mutect2, varscan2
- RPL17-C18orf32 | c.507+1917C>A | Intron (SNP) | VAF 7/33 reads (21%) | called by muse, mutect2, varscan2
- TGIF2LY | c.-1T>A | 5'UTR (SNP) | VAF 7/58 reads (12%) | catalogued as COSV100339591; called by muse, mutect2, varscan2
- ZNF271P | n.4216G>T | RNA (SNP) | VAF 4/42 reads (10%) | called by mutect2, varscan2
